Somatic mutation profile of tumor specimen TCGA-G9-6367-01A (aliquot TCGA-G9-6367-01A-11D-1786-08) from TCGA case TCGA-G9-6367, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.7 years (22,176 days).
Specimen TCGA-G9-6367-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79bfbf04-4233-4ec2-a9bb-0506b49c36d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6367-10A (Blood Derived Normal), aliquot TCGA-G9-6367-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c06cc749-0763-41e5-8d6a-e6bc02041a15

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RBM15 | c.2704G>C p.G902R | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63923139, COSV63924574; called by muse, mutect2
- LRPPRC | c.2787A>G p.R929= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV53234847; called by muse, mutect2
